Somatic mutation profile of tumor specimen TCGA-DU-7008-01A (aliquot TCGA-DU-7008-01A-11D-2024-08) from TCGA case TCGA-DU-7008, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.9 years (15,289 days).
Specimen TCGA-DU-7008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75586d48-8443-4e1d-9647-7e3129e4f662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7008-10A (Blood Derived Normal), aliquot TCGA-DU-7008-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d15883d-2de4-473e-a152-68b08d9a6abb

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 11, In Frame Del 2, Nonsense Mutation 1, RNA 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.809T>C p.F270S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519986, COSV52661272, COSV52676663, COSV52688116; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FAT2 | c.5135T>C p.I1712T | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1265447003, COSV55816657; called by muse, mutect2, varscan2
- GNPDA1 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV60942305; called by muse, mutect2, varscan2
- GTPBP4 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1004771925, COSV52987462, COSV99479353; called by muse, mutect2
- HTR2B | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | catalogued as COSV51449452; called by muse, mutect2, varscan2
- IL4I1 | c.613_615del p.K205del | In Frame Del (DEL) | VAF 19/108 reads (18%) | catalogued as rs760138718; called by pindel, varscan2
- KRTAP13-4 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1454253874, COSV100481716; called by muse, mutect2, varscan2
- LMF2 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs149785243; called by muse, mutect2, varscan2
- PC | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.35); catalogued as COSV63079804; called by muse, mutect2, varscan2
- PIEZO2 | c.8026T>A p.S2676T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53287810; called by muse, mutect2, varscan2
- SF3B1 | c.1621T>C p.S541P | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV59211069; called by muse, varscan2
- SLC25A53 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as rs1488166824, COSV62458394; called by muse, mutect2, varscan2
- TIMD4 | c.928A>T p.M310L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV50854586; called by muse, mutect2
- TMEM82 | c.1006C>A p.Q336K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV65387172; called by muse, mutect2, varscan2
- USP11 | c.1255G>A p.V419M (on ENST00000218348; = p.V376M on NM_001371072.1) | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV54473045; called by muse, mutect2, varscan2
- XK | c.716T>A p.V239D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV66119910; called by muse, mutect2, varscan2
- XKRX | c.1119A>T p.K373N | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV60707676; called by muse, mutect2, varscan2
- ZNF571 | c.1790G>A p.C597Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100143555; called by muse, mutect2, varscan2
- ATRX | c.710dup p.N237Kfs*23 | Frame Shift Ins (INS) | VAF 103/257 reads (40%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.3679_3681del p.K1227del | In Frame Del (DEL) | VAF 45/136 reads (33%) | called by mutect2, pindel, varscan2
- DLG2 | c.774C>T p.H258= | Silent (SNP) | VAF 23/183 reads (13%) | catalogued as rs199577400, COSV54633356; called by muse, mutect2, varscan2
- FAT1 | c.11043T>C p.V3681= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs766386938, COSV71673203; called by muse, mutect2, varscan2
- FGD3 | c.1753C>T p.L585= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV100491045, COSV61596484; called by muse, mutect2
- HSD17B4 | c.1983G>A p.K661= (on ENST00000414835 / NM_001199291.3; = p.K636= on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs1430676057, COSV56334596; called by muse, mutect2, varscan2
- MAP3K13 | c.843A>G p.K281= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV53986123; called by muse, mutect2, varscan2
- OR2T11 | c.837G>A p.T279= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as rs774253846, COSV100424873, COSV58185304; called by muse, mutect2
- OR9A2 | c.555C>T p.C185= | Silent (SNP) | VAF 51/244 reads (21%) | catalogued as rs372529476; called by muse, mutect2, varscan2
- PDZD4 | c.1344C>A p.P448= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV51245955; called by muse, mutect2
- PPHLN1 | c.957G>A p.L319= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV56728929, COSV56729676; called by muse, mutect2
- PPP1R16B | c.976C>T p.L326= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV55375866; called by muse, mutect2, varscan2
- ZNF791 | c.1506G>T p.G502= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV58480462; called by muse, mutect2, varscan2
- EI24P4 | n.845C>G | RNA (SNP) | VAF 114/520 reads (22%) | called by muse, mutect2, varscan2
- RASSF10 | c.-34C>T | 5'UTR (SNP) | VAF 12/33 reads (36%) | catalogued as rs1423395688; called by muse, mutect2, varscan2
